Somatic mutation profile of tumor specimen TCGA-XJ-A9DQ-01A (aliquot TCGA-XJ-A9DQ-01A-11D-A377-08) from TCGA case TCGA-XJ-A9DQ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-XJ-A9DQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 785ff04e-2a11-4f4e-a2dc-924b00e1a8c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XJ-A9DQ-10A (Blood Derived Normal), aliquot TCGA-XJ-A9DQ-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14e01071-6e88-430e-bd86-11a441e446a3

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSUN6 | c.492A>C p.E164D | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV101045750; called by muse, mutect2, varscan2
- SRCAP | c.2204T>C p.F735S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99350556; called by muse, mutect2, varscan2
- ZNF155 | c.891C>G p.F297L | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99525743; called by muse, mutect2
- EPN3 | c.888C>T p.S296= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as rs1440124926, COSV99277112; called by muse, mutect2
- LRRC4B | c.264G>A p.T88= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs531091448, COSV101210174; called by muse, varscan2
